Somatic mutation profile of tumor specimen TCGA-F7-A61W-01A (aliquot TCGA-F7-A61W-01A-11D-A28R-08) from TCGA case TCGA-F7-A61W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.7 years (18,879 days).
Specimen TCGA-F7-A61W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b61c9dd8-9681-422c-8e87-87d7e00a7b7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A61W-10A (Blood Derived Normal), aliquot TCGA-F7-A61W-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5acb462-dba6-4cb8-a26d-c74ddbf8bd52

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 42, Silent 17, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.983dup p.T329Hfs*8 | Frame Shift Ins (INS) | VAF 76/123 reads (62%) | catalogued as rs886041285, COSV52927593; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABL2 | c.2530A>T p.S844C (on ENST00000502732 / NM_007314.4; = p.S829C on NM_005158.5) | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV100772894; called by muse, mutect2, varscan2
- ACTN4 | c.1546C>A p.L516M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99400514; called by muse, mutect2, varscan2
- ADGRG7 | c.2359C>G p.L787V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56293294, COSV99841356; called by muse, mutect2, varscan2
- AKR1D1 | c.971A>T p.D324V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV99653200; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99783937; called by muse, mutect2, varscan2
- ARHGAP29 | c.3038C>T p.T1013I | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV99558621; called by muse, mutect2, varscan2
- ATP10D | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99905919; called by muse, mutect2
- BMP2 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175971832, COSV101122106; called by muse, mutect2, varscan2
- BTBD8 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100730395; called by muse, mutect2, varscan2
- COL18A1 | c.1657C>T p.L553F (on ENST00000359759 / NM_130444.3; = p.L318F on NM_030582.4) | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV100700828; called by muse, mutect2, varscan2
- CSMD3 | c.4947C>A p.D1649E (on ENST00000297405 / NM_001363185.1; = p.D1545E on NM_052900.3) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52107762; called by muse, mutect2, varscan2
- CYP4A22 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 155/396 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99595202; called by muse, mutect2, varscan2
- DCLK1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99712279; called by muse, mutect2, varscan2
- DHX36 | c.991A>T p.I331F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100273787; called by muse, mutect2, varscan2
- FRMD4A | c.1904A>G p.H635R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs751081943, COSV100662179; called by muse, mutect2, varscan2
- HERC6 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910619; called by muse, mutect2, varscan2
- HUWE1 | c.6307A>T p.K2103* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99473384; called by muse, mutect2
- IGKV3D-11 | c.168C>A p.Y56* | Nonsense Mutation (SNP) | VAF 48/198 reads (24%) | catalogued as rs373135775; called by muse, mutect2
- KIF15 | c.2392A>G p.S798G | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100393057; called by muse, mutect2, varscan2
- KIF26A | c.2833A>T p.R945W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100181397; called by muse, mutect2, varscan2
- NAA25 | c.2240A>G p.K747R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99927837; called by muse, mutect2, varscan2
- NCOR2 | c.2174A>G p.H725R | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.923); catalogued as rs376775457; called by muse, mutect2, varscan2
- NOC3L | c.1389+1G>T p.X463_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as rs753230004, COSV100993362; called by muse, mutect2, varscan2
- OR2AG2 | c.325A>G p.S109G | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1242978309, COSV100643050; called by muse, mutect2
- OR5AS1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100546329; called by muse, mutect2, varscan2
- PAQR7 | c.945T>G p.F315L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.297); catalogued as COSV100961704; called by muse, mutect2, varscan2
- PDE10A | c.1824C>G p.H608Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100605394; called by muse, mutect2, varscan2
- PLEKHG7 | c.1603C>G p.H535D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); catalogued as COSV100760152; called by muse, mutect2, varscan2
- SCNN1G | c.1586C>A p.S529Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100264358; called by muse, mutect2, varscan2
- SMCHD1 | c.3075G>T p.E1025D | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99862116; called by muse, mutect2, varscan2
- SPEG | c.8434C>A p.P2812T | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100405145; called by muse, mutect2, varscan2
- STARD5 | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV100250891; called by muse, mutect2
- TAF13 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100615499; called by muse, mutect2, varscan2
- TCF20 | c.5641A>G p.I1881V | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.584); catalogued as rs747853616, COSV100166797; called by muse, mutect2, varscan2
- TM9SF3 | c.1040A>G p.Y347C | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749640145, COSV100951869; called by muse, mutect2, varscan2
- TMEM132D | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765263700, COSV101398857; called by muse, mutect2, varscan2
- TMEM200A | c.526A>C p.K176Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99759652; called by muse, mutect2, varscan2
- TSPAN3 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs370307435; called by muse, mutect2, varscan2
- TTC3 | c.4936G>C p.E1646Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV100695805; called by muse, mutect2, varscan2
- ULK1 | c.339C>A p.D113E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV100417111; called by muse, mutect2, varscan2
- USP3 | c.1064A>T p.N355I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV99165761; called by muse, mutect2, varscan2
- UST | c.1153A>G p.T385A | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.956); catalogued as COSV100820082; called by muse, mutect2
- ZC3H15 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100552155; called by muse, mutect2, varscan2
- ZNF10 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as rs1311412106, COSV99940096; called by muse, mutect2, varscan2
- ZNF180 | c.1337T>A p.F446Y | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55419560, COSV99659992; called by muse, mutect2, varscan2
- ZNF546 | c.82A>G p.M28V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100713514; called by muse, mutect2, varscan2
- KMT2D | c.713del p.L238Cfs*23 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- P4HA1 | c.580_581del p.L194Gfs*2 | Frame Shift Del (DEL) | VAF 40/117 reads (34%) | called by mutect2, pindel, varscan2
- ACTR1A | c.96A>G p.K32= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100883726; called by muse, mutect2, varscan2
- AMER3 | c.267G>A p.V89= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100366749; called by muse, mutect2, varscan2
- APTX | c.891A>T p.V297= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV100541402; called by muse, mutect2, varscan2
- COL8A2 | c.888G>A p.G296= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100291297; called by muse, mutect2, varscan2
- DENND10 | c.753G>A p.V251= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100814017; called by muse, mutect2, varscan2
- DUS3L | c.1506A>C p.S502= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV100288375; called by muse, mutect2, varscan2
- ESS2 | c.528A>G p.A176= | Silent (SNP) | VAF 88/216 reads (41%) | catalogued as COSV99351068; called by muse, mutect2, varscan2
- GDF3 | c.786C>T p.N262= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs746944156, COSV100325350; called by muse, mutect2, varscan2
- GTF3C3 | c.1398A>G p.L466= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV99826842; called by muse, mutect2
- HYDIN | c.6486C>T p.S2162= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs201229423; called by mutect2, varscan2
- KRTAP15-1 | c.129G>T p.L43= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV61877664; called by muse, mutect2, varscan2
- MAP1B | c.501C>T p.T167= | Silent (SNP) | VAF 44/61 reads (72%) | catalogued as rs111766097; called by muse, mutect2, varscan2
- PDE7B | c.619C>T p.L207= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs747972812, COSV100368018; called by muse, mutect2, varscan2
- PREX2 | c.2055T>C p.D685= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as COSV99908691; called by muse, mutect2, varscan2
- SCAP | c.3465T>C p.H1155= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV99650831; called by muse, mutect2, varscan2
- ZBED1 | c.393G>A p.L131= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as COSV100585854; called by muse, mutect2, varscan2
- ZNF343 | c.1683A>G p.K561= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99601551; called by muse, mutect2, varscan2
